Surgical pathology report (de-identified scan), TCGA case TCGA-3H-AB3O, project TCGA-MESO (Mesothelioma), tissue source site MD Anderson Cancer Center, specimen TCGA-3H-AB3O-01A (Primary Tumor).

[page 1 of 2]
██████ M

Accession: ██████████
Specimen Date/Time:

DIAGNOSIS

- (A) LYMPH NODE, 4R, LYMPHADENECTOMY:
Two lymph nodes, no tumor present (0/2).
- (B) LYMPH NODE, STATION 7, LYMPHADENECTOMY:
One lymph node, no tumor present (0/1).
- (C) DIAPHRAGM, BIOPSY:
Portion of diaphragm, no tumor present.
- (D) RIGHT LIVER, BIOPSY:
Liver parenchyma with fibrosis, no tumor present.
- (E) RIGHT PLEURA, BIOPSY:
EPITHELIOID MALIGNANT MESOTHELIOMA.

ICD O-3
Mesothelioma, epithelioid
malignant 9052/3
Site: @ Pleura NOS C38.4
JW 6/13/14

GROSS DESCRIPTION

- (A) 4R LYMPH NODE - Received are two possible lymph nodes measuring 0.6 to 1.0 cm in greatest dimension. Specimen submitted entirely in A.
- (B) STATION 7 LYMPH NODE - Received is one possible lymph node measuring 0.6 cm in greatest dimension. Specimen submitted entirely in B.
- (C) BIOPSY OF DIAPHRAGM - Received is a single fragment of tan-pink soft tissue measuring 0.2 cm in greatest dimension. Specimen submitted entirely in C.
- (D) RIGHT LIVER BIOPSY - Received are two fragments of tan-pink soft tissue both measuring 0.2 cm in greatest dimension. Specimen submitted entirely in D.
- (E) RIGHT PLEURAL TUMOR - A single (2.3 x 1.1 x 0.9 cm) portion of pink-tan to white fibrous tissue that is entirely submitted for frozen section evaluation in E.
- *FS/DX: POSITIVE MALIGNANT MESOTHELIOMA.

CLINICAL HISTORY

Mesothelioma.

SNOMED CODES

T-2900, M-90503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

[page 2 of 2]
[Redacted] M

[Redacted]

Specimen Date/Time:

Criteria	hw 3/5/14	Yes	No

Source: NCI Genomic Data Commons file 3ef72890-e4b3-499e-a4c6-5a314c631237 (TCGA-3H-AB3O.D5828CA0-5ED9-4AF6-9E3C-CBE57826E43F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).